Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACU, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACU-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Laparoscopic segmentectomy (Segment 6)

Organ: Liver (11.5 x 6.0 x 5.0 cm)

Lesions: Mass

Size: 2.0 x 1.8 x 1.5 cm

Cut surface: Encapsulated, yellowish tan, round and solid

Gross type: Multinodular confluent

Extent: Confined to the capsule

Resection margin: Not involved, grossly (safety margin: 0.8 cm)

Remaining parenchyme: Unremarkable

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4 and TB, mass of liver x 5

RM, mass with resection margin x 1

L and NB, nontumorous liver parenchyme x 2

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JW 01/19/14

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

The worst differentiation III

The major differentiation II

Histologic type: Trabecular, acinar

Cell type: No

Fatty change: Yes (minimal)

Cholangiocarcinoma: No

Fibrous capsule formation: No

Capsular infiltration: No

Septum formation: Yes

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Vascular invasion: No

Bile duct invasion: No

Remaining liver parenchyme: Portal inflammation and fibrosis

SPECIAL STAIN: Trichrome shows portal fibrosis

[page 2 of 2]
IMMUNOHISTOCHEMISTRY:

T1: CD34 (+)
L: CD34 (-)

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703

DIAGNOSIS:

Liver, segment 6, laparoscopic segmentectomy:
Hepatocellular carcinoma

NOTE:

Suggestion :

Criteria	lw 1/15/13	Yes	No

Source: NCI Genomic Data Commons file 12a6d388-57bd-4a25-9354-a0e74f557b2e (TCGA-DD-AACU.3CA9651B-35BE-4D1E-9C91-BF3029931F32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).